Somatic mutation profile of tumor specimen TCGA-EE-A2ML-06A (aliquot TCGA-EE-A2ML-06A-11D-A197-08) from TCGA case TCGA-EE-A2ML, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.6 years (15,912 days).
Specimen TCGA-EE-A2ML-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93476d18-cd60-477c-9c19-73847870f711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2ML-10A (Blood Derived Normal), aliquot TCGA-EE-A2ML-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d5e2940-5578-4f66-8023-73014f45a725

The open-access MAF lists 666 somatic variants for this specimen: 436 protein-altering or splice-affecting, 215 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 215, Nonsense Mutation 34, RNA 9, Splice Region 6, Splice Site 6, Intron 6, Frame Shift Del 2, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs730880403, COSV51757334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MED13 | c.6047C>T p.P2016L | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1567938478, COSV67266342; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3509G>A p.R1170K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757421299, COSV64676729; called by muse, mutect2, varscan2
- ABI1 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1564466161, COSV61019463; called by muse, mutect2, varscan2
- ACOXL | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1177148225, COSV61329396; called by muse, mutect2, varscan2
- ACTN4 | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as COSV53149407; called by muse, mutect2, varscan2
- ACTR1B | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs535879401, COSV56705411; called by muse, mutect2, varscan2
- ACTRT1 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64419902; called by muse, mutect2, varscan2
- ACTRT2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866635436, COSV65759512; called by muse, mutect2
- ADAM29 | c.1850A>T p.H617L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV63667136; called by muse, mutect2, varscan2
- ADAM7 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV51545300; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV101001172, COSV65897056; called by muse, mutect2
- ADGRB1 | c.2610C>G p.I870M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60092575, COSV60102199; called by muse, mutect2, varscan2
- ADGRG4 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV54963502; called by muse, mutect2, varscan2
- ADORA3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs764124230, COSV53986994; called by muse, mutect2, varscan2
- AFDN | c.854A>T p.Y285F | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV60053429; called by muse, mutect2, varscan2
- AGAP6 | c.1337C>T p.S446L (on ENST00000374056 / NM_001365867.1; = p.S469L on NM_001077665.2) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs782281904, COSV65017834; called by muse, mutect2, varscan2
- AGBL4 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs1352783869, COSV61895296; called by muse, varscan2
- AHNAK2 | c.8923G>A p.D2975N | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV60918229; called by muse, mutect2, varscan2
- AKR1C2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs139521690, COSV66334076; called by muse, varscan2
- AKT2 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV60909956; called by muse, mutect2, varscan2
- AMER1 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs781777369, COSV57665827; called by muse, mutect2, varscan2
- ANK3 | c.9318A>T p.E3106D | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.967); catalogued as COSV55076291; called by muse, mutect2, varscan2
- ANK3 | c.5069C>T p.S1690L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV55075370; called by muse, mutect2, varscan2
- ANK3 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55076309; called by muse, mutect2, varscan2
- ANKS3 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58511087; called by muse, mutect2, varscan2
- ANO4 | c.2033G>A p.R678K (on ENST00000392977 / NM_001286615.2; = p.R643K on NM_178826.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV54608899; called by muse, mutect2, varscan2
- ANXA5 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56639939; called by muse, mutect2, varscan2
- AP3B1 | c.2009A>G p.N670S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs757825991, COSV54890765; called by muse, mutect2, varscan2
- APLNR | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57243760; called by muse, mutect2, varscan2
- AQP8 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV54846983, COSV54847773; called by muse, varscan2
- AQP9 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54970082, COSV54970211; called by muse, mutect2, varscan2
- ARHGAP30 | c.3226C>T p.P1076S (on ENST00000368013 / NM_001025598.2; = p.P865S on NM_181720.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV63518693; called by muse, mutect2, varscan2
- ARHGAP36 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52270764; called by muse, mutect2
- ARHGEF17 | c.3448C>T p.Q1150* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55236529; called by muse, mutect2, varscan2
- ASL | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1405344068, COSV59188543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52466990; called by muse, mutect2, varscan2
- ATAD5 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as COSV58977882; called by mutect2, varscan2
- ATF7IP | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53775961; called by muse, mutect2, varscan2
- ATP13A4 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs778752011, COSV55069321; called by muse, mutect2, varscan2
- ATP23 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55686479; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs759959455, COSV59473910; called by muse, mutect2, varscan2
- BEND5 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV65716905; called by muse, mutect2, varscan2
- BICRAL | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58407918; called by muse, mutect2, varscan2
- BRCA2 | c.6319C>T p.P2107S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV66453105, COSV66458567; called by muse, mutect2, varscan2
- BRPF3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1298654843, COSV60209247; called by muse, mutect2, varscan2
- BRWD3 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64752362; called by muse, mutect2, varscan2
- BSND | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV64871281; called by muse, mutect2, varscan2
- C10orf71 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60505818; called by muse, varscan2
- C10orf88 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.912); catalogued as rs1439630138, COSV64404297; called by muse, mutect2, varscan2
- CAMK4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV56679945; called by muse, mutect2, varscan2
- CATSPER3 | c.1138A>G p.M380V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772918730, COSV50948974; called by muse, mutect2
- CBLN2 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV54052661; called by muse, mutect2, varscan2
- CCDC115 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99383785; called by muse, mutect2, varscan2
- CCDC39 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs755372916, COSV56479163; called by muse, mutect2, varscan2
- CCDC54 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs757767034, COSV53759634; called by muse, mutect2, varscan2
- CCDC80 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs1206141546, COSV99244999; called by muse, mutect2, varscan2
- CCDC88C | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1472117058, COSV66232694; called by mutect2, varscan2
- CCKAR | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99810377; called by muse, mutect2, varscan2
- CCKAR | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV99810378; called by muse, mutect2, varscan2
- CCKAR | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs532932146, COSV55163371; called by muse, mutect2, varscan2
- CCKBR | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs750804920, COSV58102065; called by muse, mutect2, varscan2
- CCNA1 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV55223457; called by muse, mutect2, varscan2
- CCNH | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56926006; called by muse, mutect2, varscan2
- CD226 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1289810110, COSV54615259; called by muse, mutect2, varscan2
- CD5L | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs545632901, COSV63822637; called by muse, varscan2
- CDC25A | c.760A>T p.N254Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV56771944; called by muse, mutect2, varscan2
- CEMIP | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.239); catalogued as COSV54998635; called by muse, mutect2, varscan2
- CERKL | c.1537G>A p.D513N (on ENST00000339098 / NM_001030311.2; = p.D487N on NM_201548.5) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV59212471; called by muse, mutect2, varscan2
- CFAP74 | c.4273G>A p.A1425T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV60587728; called by muse, mutect2, varscan2
- CFHR4 | c.188C>T p.S63L (on ENST00000367416 / NM_001201551.2; = p.S64L on NM_006684.5) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV52233349; called by muse, mutect2, varscan2
- CHST8 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1568328772, COSV52859012; called by muse, mutect2, varscan2
- CLASP2 | c.911T>C p.F304S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56291312; called by muse, mutect2, varscan2
- CMIP | c.1758C>T p.I586= (on ENST00000537098 / NM_198390.2; = p.I492= on NM_030629.3) | Splice Region (SNP) | VAF 66/178 reads (37%) | catalogued as COSV67699294; called by muse, mutect2, varscan2
- CNNM2 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64001435; called by muse, mutect2, varscan2
- CNR1 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV62988142, COSV62988733; called by muse, mutect2, varscan2
- CNTNAP2 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs766777011, COSV62164786; called by muse, mutect2, varscan2
- COL11A1 | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62193485, COSV62195632; called by muse, mutect2, varscan2
- COL5A3 | c.5160G>A p.W1720* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as rs751812549, COSV53417284; called by muse, mutect2, varscan2
- COL6A6 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV62034379; called by muse, mutect2, varscan2
- COL7A1 | c.5560G>A p.G1854R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146234310; called by muse, mutect2, varscan2
- COX10 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs768183008, COSV99886782; called by muse, varscan2
- CPNE4 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV70193225; called by muse, mutect2
- CPNE6 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53746002; called by muse, mutect2
- CPSF3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV53011335; called by muse, mutect2, varscan2
- CRADD | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100257686; called by mutect2, varscan2
- CRADD | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100257688; called by muse, mutect2, varscan2
- CSTA | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52612760; called by mutect2, varscan2
- CTNND2 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV58917215; called by muse, mutect2, varscan2
- CTNND2 | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs745818422, COSV100479685, COSV58867022; called by muse, mutect2, varscan2
- CUL9 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52733030; called by muse, mutect2, varscan2
- CUX1 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV52911206; called by muse, mutect2, varscan2
- CWH43 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1164954931, COSV56942812; called by muse, mutect2, varscan2
- CYP2C18 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53669658; called by muse, mutect2, varscan2
- CYP2C8 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs867606712, COSV64877177; called by muse, mutect2, varscan2
- CYP4F3 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV55412842; called by muse, mutect2, varscan2
- CYTIP | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs753626069, COSV99938805; called by muse, mutect2, varscan2
- DAB2IP | c.1793C>T p.P598L (on ENST00000408936; = p.P570L on NM_032552.3) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); catalogued as COSV52265996; called by muse, mutect2, varscan2
- DCSTAMP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs749203316, COSV52577033; called by muse, mutect2, varscan2
- DDX60 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101190526; called by muse, mutect2, varscan2
- DDX60 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs776772733, COSV101190528; called by muse, mutect2, varscan2
- DEFB112 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59182974; called by muse, mutect2, varscan2
- DGKK | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs376014418, COSV65707507; called by muse, mutect2, varscan2
- DGUOK | c.546C>G p.S182R | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV51204588; called by muse, mutect2, varscan2
- DHCR7 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs765908713, COSV62796156; called by muse, mutect2, varscan2
- DLGAP3 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs267598572, COSV52396617; called by muse, mutect2, varscan2
- DMRTC2 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV54188009; called by muse, mutect2, varscan2
- DNAH1 | c.10066C>T p.Q3356* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV70234423; called by muse, mutect2, varscan2
- DNAH5 | c.7399C>T p.P2467S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV54245960, COSV54249052; called by muse, mutect2, varscan2
- DNAH5 | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542591554, COSV54202517; called by muse, mutect2, varscan2
- DNAJC10 | c.20A>T p.K7I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV51144249; called by muse, mutect2, varscan2
- DONSON | c.421T>G p.S141A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as COSV51679115; called by muse, mutect2, varscan2
- DPPA2 | c.877T>A p.L293I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as COSV72118272; called by muse, mutect2, varscan2
- DPRX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs761892759, COSV64949245; called by muse, mutect2, varscan2
- DRGX | c.210A>G p.I70M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65137311; called by muse, mutect2, varscan2
- DSC2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as rs769787593, COSV51868146, COSV99199915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as COSV56809944, COSV56814934; called by muse, mutect2, varscan2
- DST | c.4984C>T p.L1662F | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99757965; called by muse, mutect2, varscan2
- DYSF | c.2443C>T p.L815F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1559168029, COSV50532558; called by muse, mutect2, varscan2
- EDN3 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61109837; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1579C>T p.P527S (on ENST00000361735 / NM_015935.5; = p.P441S on NM_014955.3) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); catalogued as rs865948011, COSV62282737; called by muse, mutect2, varscan2
- EFHB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55552277; called by muse, mutect2, varscan2
- ELFN2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1201984546, COSV68746121; called by muse, mutect2, varscan2
- ELOA | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs759049246, COSV69311139; called by muse, mutect2
- ENC1 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1250873067, COSV56630805; called by muse, mutect2, varscan2
- ENPP3 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV62956018; called by muse, mutect2, varscan2
- EPB41L4B | c.416G>A p.W139* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV65798394; called by muse, mutect2, varscan2
- ERP27 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV56764542; called by muse, mutect2, varscan2
- FAAH2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254403222, COSV66506076, COSV66506223; called by muse, mutect2, varscan2
- FABP2 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1391975744, COSV56788606; called by muse, mutect2, varscan2
- FAM135B | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748683046, COSV50536124; called by muse, mutect2, varscan2
- FAM71A | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV54236872; called by muse, varscan2
- FAM83B | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs370742915; called by muse, mutect2, varscan2
- FANK1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs770914661, COSV64156223; called by muse, mutect2, varscan2
- FAT3 | c.4636C>T p.R1546* | Nonsense Mutation (SNP) | VAF 138/490 reads (28%) | catalogued as rs866154457, COSV53094050; called by muse, mutect2, varscan2
- FBXL19 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1400290303, COSV57944942; called by muse, mutect2, varscan2
- FBXO40 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV57523058; called by muse, mutect2, varscan2
- FBXO6 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV52418415; called by muse, mutect2
- FILIP1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs758951374, COSV52726300; called by muse, mutect2, varscan2
- FLRT3 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV54037009; called by muse, mutect2, varscan2
- FPGT | c.1628T>C p.V543A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100907334; called by muse, mutect2, varscan2
- FRA10AC1 | c.51_52del p.C17Wfs*12 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs764976937; called by pindel, varscan2
- FRMPD2 | c.3170C>T p.S1057F | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV59722341; called by muse, varscan2
- FRMPD2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as rs1468559208, COSV59722350; called by muse, mutect2, varscan2
- FYB2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as rs866866257, COSV58585657; called by muse, mutect2
- FYB2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs868551385, COSV58588129; called by muse, mutect2, varscan2
- GAB4 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV68754899; called by muse, mutect2, varscan2
- GABRB3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV54678496; called by muse, varscan2
- GALNT2 | c.1314-1G>T p.X438_splice | Splice Site (SNP) | VAF 29/88 reads (33%) | catalogued as COSV64196953; called by muse, mutect2, varscan2
- GALNT5 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52037643; called by muse, mutect2, varscan2
- GAPVD1 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780436212, COSV52925925; called by muse, mutect2, varscan2
- GAS2 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53411396; called by muse, mutect2, varscan2
- GBE1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70102189; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- GPA33 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV63302330; called by muse, mutect2, varscan2
- GPC5 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs199697192, COSV65573069; called by muse, mutect2, varscan2
- GPCPD1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV66831585; called by muse, varscan2
- GPR149 | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV67669305; called by muse, mutect2, varscan2
- GRIA1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1561754506, COSV53619566; called by muse, mutect2, varscan2
- GRIN2B | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74207316, COSV74207686; called by muse, varscan2
- GRM7 | c.765A>T p.R255S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV63163132; called by muse, mutect2, varscan2
- GRM7 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs140116291; called by muse, mutect2, varscan2
- GRM7 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63163153; called by muse, mutect2, varscan2
- GUCY2C | c.2317C>T p.R773* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as rs1162405939, COSV53789155, COSV53794471; called by muse, mutect2, varscan2
- GUCY2F | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs755278764, COSV54303203; called by muse, mutect2, varscan2
- HHIP | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56843117; called by muse, varscan2
- HIP1 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782614004, COSV61190313; called by muse, mutect2, varscan2
- HNRNPH3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV56263098; called by muse, mutect2, varscan2
- HPS1 | c.1103C>T p.T368I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV57268425; called by muse, varscan2
- HRH2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99199735; called by muse, varscan2
- IGHV3-16 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.977); catalogued as rs1444101576; called by muse, mutect2, varscan2
- IL20RA | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs757354700, COSV57359922; called by muse, mutect2, varscan2
- IL21R | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61972110; called by muse, mutect2, varscan2
- ITK | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV70061776; called by muse, mutect2, varscan2
- ITPKB | c.2553+1G>T p.X851_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV55267742; called by muse, mutect2, varscan2
- ITPR2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101189750, COSV67274739; called by muse, mutect2, varscan2
- KAT6A | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV55906292; called by muse, mutect2, varscan2
- KCNA6 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54975298; called by muse, mutect2, varscan2
- KCNH5 | c.1226G>A p.W409* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV59772710; called by muse, mutect2, varscan2
- KCNK13 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs768343772, COSV56416229; called by muse, mutect2, varscan2
- KCNQ5 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59677326; called by muse, mutect2
- KHDRBS2 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV55483166; called by muse, mutect2, varscan2
- KIF4B | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs760862480, COSV70530922; called by muse, mutect2, varscan2
- KIF4B | c.1923G>A p.W641* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV70530928; called by muse, mutect2, varscan2
- KLHL38 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV58088673; called by muse, mutect2, varscan2
- KLRC2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1432797801, COSV67899859; called by muse, mutect2, varscan2
- KPRP | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as COSV64222676; called by muse, mutect2, varscan2
- KRT84 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs143172691; called by muse, mutect2, varscan2
- LAMP5 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.022); catalogued as COSV55717658; called by muse, mutect2
- LFNG | c.623G>C p.R208P (on ENST00000222725 / NM_001040167.2; = p.R79P on NM_002304.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs369448148, COSV56070573; called by muse, mutect2, varscan2
- LGR6 | c.488C>T p.S163F (on ENST00000367278 / NM_001017403.1; = p.S111F on NM_021636.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55152606; called by muse, mutect2, varscan2
- LIFR | c.2830C>T p.H944Y | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV54697585; called by muse, mutect2, varscan2
- LIMCH1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374022264; called by muse, mutect2, varscan2
- LIMCH1 | c.2755C>T p.H919Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58293528; called by muse, mutect2, varscan2
- LIMK2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs775710676, COSV59184005; called by muse, mutect2
- LIN7A | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54026434; called by muse, mutect2, varscan2
- LIPI | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV60708584; called by mutect2, varscan2
- LRIG3 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.617); catalogued as COSV57868572; called by muse, mutect2, varscan2
- LRP1B | c.6578G>T p.G2193V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV67186898, COSV67195934, COSV67234394; called by muse, mutect2, varscan2
- LRP1B | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67209148; called by muse, mutect2, varscan2
- LRRIQ3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs765391855, COSV63041539; called by muse, mutect2, varscan2
- LYSMD1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64420038, COSV64420335; called by muse, mutect2, varscan2
- MACROD2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54037022; called by muse, mutect2, varscan2
- MAG | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs1432192903, COSV62702409; called by muse, mutect2, varscan2
- MAGEA4 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 34/51 reads (67%) | catalogued as COSV52340262; called by muse, mutect2, varscan2
- MAGEC1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.665); catalogued as rs376659171, COSV53567584; called by muse, mutect2, varscan2
- MAGI1 | c.3291G>T p.R1097S (on ENST00000402939 / NM_001033057.2; = p.R1126S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV58339953, COSV58343190; called by muse, mutect2, varscan2
- MAP3K21 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV64042280, COSV64042367, COSV64042524; called by muse, mutect2, varscan2
- MARCO | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs765172623, COSV59052524, COSV59056488; called by muse, mutect2, varscan2
- MAST1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52252720; called by muse, mutect2, varscan2
- MC3R | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54764742; called by muse, mutect2, varscan2
- MCHR2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV56007278; called by muse, mutect2, varscan2
- MERTK | c.2487G>A p.L829= | Splice Region (SNP) | VAF 19/49 reads (39%) | catalogued as COSV54934334; called by muse, mutect2, varscan2
- MICAL3 | c.4114C>T p.P1372S | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV71588831; called by muse, mutect2, varscan2
- MICAL3 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV71588832; called by muse, mutect2, varscan2
- MME | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 88/331 reads (27%) | catalogued as COSV64709719; called by muse, mutect2, varscan2
- MMS22L | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51525237; called by muse, mutect2, varscan2
- MORC1 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as COSV51728372; called by muse, mutect2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by muse, mutect2, varscan2
- MRPL1 | c.101T>G p.V34G | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.543); catalogued as COSV59676471; called by muse, mutect2, varscan2
- MRPL47 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52023817; called by muse, mutect2, varscan2
- MRTFB | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.115); catalogued as COSV57956242, COSV57960796; called by muse, mutect2, varscan2
- MS4A1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV100619366; called by muse, mutect2, varscan2
- MS4A1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs777259260, COSV61941653; called by muse, mutect2, varscan2
- MTUS2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as COSV70920308; called by muse, mutect2, varscan2
- MUC16 | c.32588C>T p.S10863L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV67485854; called by muse, mutect2, varscan2
- MUC16 | c.32435C>A p.T10812K | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1337526118, COSV67485865; called by muse, mutect2, varscan2
- MYCBP2 | c.9058C>T p.H3020Y (on ENST00000357337; = p.H3058Y on NM_015057.5) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV62034936; called by muse, mutect2, varscan2
- MYH1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV56848008, COSV56855146; called by muse, mutect2, varscan2
- MYH11 | c.121del p.E41Rfs*39 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as COSV100259721; called by mutect2, pindel, varscan2
- MYH13 | c.3990G>T p.K1330N | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99354598; called by muse, mutect2, varscan2
- MYO5B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV53228096; called by muse, mutect2, varscan2
- NARS2 | c.1402T>C p.F468L | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55250671, COSV55254766; called by muse, mutect2, varscan2
- NAV1 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1359511612, COSV55223967; called by muse, mutect2, varscan2
- NBAS | c.4058T>C p.L1353P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55734139; called by muse, mutect2, varscan2
- NBEA | c.2796G>A p.W932* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV59814207; called by muse, mutect2
- NCKAP5L | c.2486G>C p.R829P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV60132612; called by muse, mutect2, varscan2
- NDST4 | c.2077C>T p.L693F | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52133046; called by muse, mutect2, varscan2
- NEB | c.8554G>A p.V2852M | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as rs1256097684, COSV51449750; called by muse, mutect2, varscan2
- NFIC | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59414839; called by muse, mutect2, varscan2
- NIM1K | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs1205365939, COSV58144742; called by muse, mutect2, varscan2
- NIPAL4 | c.1069T>A p.F357I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV57437282; called by muse, mutect2, varscan2
- NKAIN3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs201185620, COSV60659818; called by muse, mutect2, varscan2
- NLRP14 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1431100611, COSV55070886; called by muse, mutect2, varscan2
- NOP9 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs370301926; called by muse, mutect2, varscan2
- NPC1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52582323; called by muse, mutect2, varscan2
- NPHP3 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs200233813, COSV58129388, COSV58130515; called by muse, mutect2, varscan2
- NPTX2 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55718607; called by muse, mutect2, varscan2
- NPY2R | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1318855113, COSV61529319; called by muse, mutect2, varscan2
- NUAK2 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV65682435; called by muse, varscan2
- OR11L1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs768876019, COSV100869464, COSV63314922; called by muse, mutect2, varscan2
- OR13G1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1360103231, COSV62943929, COSV62944575; called by muse, mutect2, varscan2
- OR1N2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV65461063; called by muse, mutect2, varscan2
- OR2T33 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1336471030, COSV58817329; called by muse, varscan2
- OR4A47 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV71444904; called by muse, mutect2, varscan2
- OR4K5 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60002438; called by muse, mutect2, varscan2
- OR52R1 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61889173; called by muse, mutect2, varscan2
- OR5D18 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61738322; called by muse, mutect2, varscan2
- OR5L1 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1359346480, COSV61734099, COSV61735089; called by muse, mutect2, varscan2
- OR8J1 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57319663; called by muse, mutect2, varscan2
- OR8K5 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57890552; called by muse, mutect2, varscan2
- PACSIN1 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV55060683; called by muse, mutect2, varscan2
- PACSIN2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV54322443; called by muse, mutect2, varscan2
- PADI3 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV64935710; called by muse, mutect2, varscan2
- PAK5 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as rs781148117, COSV62024554, COSV62026126; called by muse, mutect2, varscan2
- PAPPA | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV60290020; called by muse, varscan2
- PARN | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58369846; called by muse, mutect2, varscan2
- PCDH18 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); catalogued as COSV100787328, COSV61267675; called by muse, mutect2, varscan2
- PCDHGA1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV65296862; called by muse, mutect2, varscan2
- PCDHGB5 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs368407532, COSV53973969; called by muse, mutect2, varscan2
- PCLO | c.10082C>T p.A3361V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs867036885, COSV61622277, COSV61658785; called by muse, mutect2
- PCM1 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.911); catalogued as COSV61518561; called by muse, mutect2, varscan2
- PDCD1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs750496363, COSV57691950, COSV57692171; called by muse, mutect2
- PDE1C | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1225158489, COSV58512683, COSV58526556; called by muse, mutect2, varscan2
- PHACTR4 | c.1258C>T p.R420* (on ENST00000373839 / NM_001350159.2; = p.R430* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as rs771901291, COSV65784915; called by muse, mutect2, varscan2
- PKD1L2 | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1386162123, COSV61418662; called by muse, mutect2, varscan2
- PKHD1 | c.1937G>A p.W646* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as CM041057, COSV100584907, COSV61890519; called by muse, mutect2, varscan2
- PKHD1L1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.609); catalogued as COSV65750337; called by muse, mutect2, varscan2
- PLA2G3 | c.1065G>A p.Q355= | Splice Region (SNP) | VAF 39/134 reads (29%) | catalogued as rs374461306; called by muse, mutect2, varscan2
- PLCE1 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV53366757; called by muse, mutect2, varscan2
- PLEKHA7 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1309897226, COSV63049802; called by muse, mutect2, varscan2
- POGK | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.478); catalogued as rs527354607, COSV63311985, COSV63312223; called by muse, mutect2, varscan2
- PPM1L | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV55569153; called by muse, mutect2, varscan2
- PPP4R4 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100428255, COSV58557342; called by muse, mutect2, varscan2
- PPP6C | c.237+1G>C p.X79_splice | Splice Site (SNP) | VAF 17/30 reads (57%) | catalogued as COSV65208838; called by muse, mutect2, varscan2
- PRB3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54392645; called by muse, varscan2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRLR | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51499407; called by muse, mutect2, varscan2
- PRR15L | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 88/144 reads (61%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.085); catalogued as COSV99846531; called by muse, varscan2
- PRUNE2 | c.8629G>A p.E2877K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56319207; called by muse, mutect2, varscan2
- PSG2 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV68884036; called by muse, mutect2, varscan2
- PTGS2 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66571225; called by muse, mutect2, varscan2
- PTPRN2 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as COSV67056587; called by muse, mutect2, varscan2
- PXDNL | c.3376C>T p.L1126F | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62488089, COSV62496222; called by muse, mutect2, varscan2
- RAD9A | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.089); catalogued as COSV57237850; called by muse, mutect2, varscan2
- RASGRF1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs758583458, COSV69179108; called by muse, mutect2, varscan2
- RASSF6 | c.457G>A p.E153K (on ENST00000342081 / NM_201431.2; = p.E121K on NM_177532.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV56717569; called by muse, mutect2, varscan2
- RBKS | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV56223917; called by muse, mutect2, varscan2
- RBP3 | c.3460T>C p.F1154L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as rs1565769426; called by muse, mutect2, varscan2
- RECK | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65036108; called by muse, mutect2, varscan2
- REV3L | c.6640C>A p.P2214T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV62622250; called by muse, mutect2, varscan2
- RFPL1 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV62978829; called by muse, mutect2, varscan2
- RGS22 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV62666235; called by muse, mutect2, varscan2
- RHBG | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV54809052; called by muse, varscan2
- RIMBP2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV55481427; called by muse, mutect2, varscan2
- RNASE11 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs112711544, COSV60087298; called by muse, mutect2, varscan2
- RNF125 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54186463; called by muse, mutect2, varscan2
- SAMD7 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV59420645; called by muse, mutect2, varscan2
- SAMD9L | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV59084421; called by muse, mutect2, varscan2
- SATB1 | c.2012A>C p.D671A | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113314; called by muse, mutect2, varscan2
- SCN11A | c.5234G>A p.R1745Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762191660, COSV56567167; called by muse, mutect2, varscan2
- SCN3B | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs764587765, COSV54798916; called by muse, mutect2
- SDR42E1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61094938; called by muse, mutect2, varscan2
- SERPINA6 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58584246, COSV58586630; called by muse, mutect2, varscan2
- SGSM1 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV68512652; called by muse, mutect2, varscan2
- SHISA3 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV59980427; called by muse, mutect2, varscan2
- SIGLEC11 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs926382153, COSV68567804; called by muse, mutect2
- SIN3B | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99931862; called by muse, mutect2, varscan2
- SLC1A6 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55673293; called by muse, mutect2
- SLC22A2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs138397321; called by muse, mutect2, varscan2
- SLC22A5 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM992670, COSV55372076; called by muse, mutect2, varscan2
- SLC38A3 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs762128354, COSV68844127; called by muse, mutect2, varscan2
- SLC46A3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57183786; called by muse, mutect2, varscan2
- SLC6A1 | c.953+1G>A p.X318_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV55118145; called by muse, mutect2, varscan2
- SLC6A12 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761912292, COSV62885904; called by muse, mutect2, varscan2
- SLC7A13 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs186513758, COSV99879026; called by muse, mutect2, varscan2
- SLC7A6 | c.1034T>A p.V345E | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50450556; called by muse, mutect2, varscan2
- SLC8A1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV60493161; called by muse, mutect2, varscan2
- SLCO1A2 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV56608655; called by muse, mutect2, varscan2
- SLCO2A1 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV60488361; called by muse, mutect2, varscan2
- SNX33 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV57913450; called by muse, mutect2, varscan2
- SPATS1 | c.759-1G>A p.X253_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV55824526; called by muse, varscan2
- SPINK5 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as rs762756312, COSV56260532; called by muse, mutect2
- SPOCK3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV62734042, COSV62741008; called by muse, mutect2, varscan2
- SPTA1 | c.4608G>A p.R1536= | Splice Region (SNP) | VAF 9/68 reads (13%) | catalogued as rs371290853; called by muse, mutect2, varscan2
- SPTB | c.5462C>T p.P1821L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1304147798, COSV67634418; called by muse, mutect2, varscan2
- SPTBN2 | c.5558G>A p.S1853N | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.777); catalogued as COSV59459344; called by muse, mutect2, varscan2
- SSH3 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57386277; called by muse, mutect2, varscan2
- SSRP1 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV53481038, COSV99554740; called by muse, mutect2, varscan2
- SSTR1 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV57457356; called by muse, mutect2, varscan2
- ST3GAL6 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99505057; called by muse, mutect2, varscan2
- STAB2 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV66345062; called by muse, mutect2, varscan2
- STEAP4 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57330987; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3245G>A p.G1082E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV59136118; called by muse, mutect2, varscan2
- STYK1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV50012985; called by muse, mutect2, varscan2
- SVEP1 | c.7202G>A p.G2401E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334485976, COSV52842770; called by muse, mutect2, varscan2
- SYVN1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV99589173; called by muse, mutect2, varscan2
- TACC2 | c.7787C>T p.P2596L (on ENST00000334433; = p.P674L on NM_006997.4) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV53287640; called by muse, mutect2
- TAS1R1 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV60229683; called by muse, mutect2, varscan2
- TATDN1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs148032742; called by muse, mutect2, varscan2
- TBC1D1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV54722576, COSV54725376; called by muse, mutect2, varscan2
- TCAIM | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61240181, COSV61242324; called by muse, mutect2, varscan2
- TDRD5 | c.2220G>A p.W740* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV54242477; called by muse, mutect2, varscan2
- TENM2 | c.7184G>A p.G2395E (on ENST00000518659 / NM_001122679.2; = p.G2156E on NM_001080428.3) | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69138692; called by muse, mutect2
- TENM3 | c.5777C>T p.T1926M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs373225091; called by muse, mutect2, varscan2
- TFCP2 | c.1397T>A p.I466N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV56935314; called by muse, mutect2, varscan2
- TGFBR2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV55448358, COSV55453645; called by muse, mutect2, varscan2
- TGFBRAP1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.097); catalogued as COSV51515161; called by muse, mutect2, varscan2
- TGM1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as CM153359, COSV52864949; called by muse, mutect2, varscan2
- THBS2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64681488; called by muse, mutect2, varscan2
- THRB | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.977); catalogued as COSV54981903; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- TIE1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65250985; called by muse, mutect2, varscan2
- TIE1 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65249857; called by muse, mutect2, varscan2
- TLN2 | c.3932C>T p.S1311L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868248184, COSV100169516; called by muse, mutect2
- TMEM132D | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV70619374; called by muse, mutect2, varscan2
- TMEM159 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51786536; called by muse, mutect2, varscan2
- TMEM200A | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51648640, COSV51660625; called by muse, mutect2, varscan2
- TMEM37 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV50030631; called by muse, mutect2, varscan2
- TNNI3K | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58555881; called by muse, mutect2, varscan2
- TNR | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 46/114 reads (40%) | catalogued as rs776846663, COSV54867827; called by muse, mutect2, varscan2
- TNXB | c.4000G>A p.G1334S (on ENST00000647633; = p.G1087S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/441 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64486756; called by muse, mutect2, varscan2
- TP63 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV53217338; called by muse, mutect2, varscan2
- TPTE | c.367C>T p.P123S (on ENST00000618007 / NM_199261.4; = p.P105S on NM_199259.4) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs778635152; called by muse, mutect2, varscan2
- TRABD2A | c.1112C>T p.P371L (on ENST00000409520 / NM_001277053.2; = p.P322L on NM_001080824.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV52878137; called by muse, mutect2, varscan2
- TRAPPC10 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs755257738, COSV52380593; called by muse, mutect2, varscan2
- TRAV4 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.241); catalogued as rs1018332964; called by mutect2, varscan2
- TRAV9-2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs747774716; called by muse, mutect2, varscan2
- TRIM29 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 66/126 reads (52%) | catalogued as COSV59281833; called by muse, mutect2, varscan2
- TRIM35 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV100542819; called by muse, varscan2
- TRIM36 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767008678, COSV56691797; called by muse, mutect2, varscan2
- TRIM51 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV55270060; called by muse, mutect2, varscan2
- TRIM71 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV67470761, COSV67472322; called by muse, mutect2, varscan2
- TRIP12 | c.1911G>A p.E637= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as rs748724504, COSV52270821; called by muse, mutect2, varscan2
- TRPM6 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs540413619, COSV62520135; called by muse, mutect2, varscan2
- TRPV5 | c.86G>A p.W29* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as COSV54688870; called by muse, mutect2, varscan2
- TSGA10 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs766621806, COSV61822696; called by muse, mutect2, varscan2
- TSPYL2 | c.2082A>T p.*694Yext*115 | Nonstop Mutation (SNP) | VAF 21/29 reads (72%) | catalogued as COSV64921406; called by mutect2, varscan2
- TTN | c.34765C>T p.P11589S (on ENST00000591111; = p.P10662S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | PolyPhen benign (0.007); catalogued as COSV60175536, COSV60245794, COSV60274602; called by muse, mutect2, varscan2
- TTN | c.33244C>T p.P11082S (on ENST00000591111; = p.P10155S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | PolyPhen benign (0.025); catalogued as COSV59938869; called by muse, mutect2, varscan2
- TTN | c.28682G>A p.R9561K (on ENST00000591111; = p.R8634K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | PolyPhen benign (0); catalogued as rs760859295, COSV60274631; called by muse, mutect2, varscan2
- TTN | c.26272G>A p.E8758K (on ENST00000591111; = p.E7831K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | PolyPhen benign (0.21); catalogued as rs1560584120, COSV60274656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.18813T>A p.D6271E (on ENST00000591111; = p.D5344E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | PolyPhen benign (0.415); catalogued as COSV60274669; called by muse, mutect2, varscan2
- TTN | c.6907G>A p.D2303N (on ENST00000591111; = p.D2257N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | PolyPhen benign (0.003); catalogued as rs779125886, COSV59978249, COSV60274688; called by muse, mutect2, varscan2
- TTN | c.5077G>A p.D1693N (on ENST00000591111; = p.D1647N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV60274738; called by muse, mutect2, varscan2
- TTN | c.2564T>G p.I855S (on ENST00000591111; = p.I809S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | PolyPhen possibly damaging (0.475); catalogued as COSV60274789; called by muse, mutect2, varscan2
- TTPAL | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99375498; called by muse, mutect2, varscan2
- TTPAL | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52829605; called by muse, mutect2, varscan2
- UGT2B28 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV59430877, COSV59434501; called by muse, mutect2, varscan2
- UMPS | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV51738638; called by muse, mutect2, varscan2
- UNC13C | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52871167, COSV99512840; called by muse, mutect2, varscan2
- USH2A | c.7090C>T p.L2364F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56419187; called by muse, mutect2
- USP11 | c.2549G>A p.R850Q (on ENST00000218348; = p.R807Q on NM_001371072.1) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV54475415, COSV54475496; called by muse, mutect2, varscan2
- USP24 | c.7121C>T p.P2374L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53772229; called by muse, varscan2
- VIP | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV65888758; called by muse, mutect2, varscan2
- VNN2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58473199; called by muse, mutect2, varscan2
- WASHC5 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV59199648; called by muse, mutect2, varscan2
- WDR36 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.951); catalogued as COSV101550987; called by muse, mutect2, varscan2
- WNT3A | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.139); catalogued as COSV52733132; called by muse, mutect2, varscan2
- XIRP1 | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV61137300; called by muse, mutect2, varscan2
- XPO5 | c.648G>A p.K216= | Splice Region (SNP) | VAF 17/79 reads (22%) | catalogued as rs1361469688, COSV99541163; called by muse, mutect2, varscan2
- YTHDC2 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV50750451; called by muse, mutect2, varscan2
- ZNF160 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62000625; called by muse, mutect2, varscan2
- ZNF213 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV67728204; called by muse, mutect2, varscan2
- ZNF214 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53483256; called by muse, mutect2, varscan2
- ZNF214 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 59/213 reads (28%) | catalogued as COSV53483269; called by muse, mutect2, varscan2
- ZNF275 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100936352; called by muse, mutect2, varscan2
- ZNF28 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1264055429, COSV60424892; called by muse, mutect2, varscan2
- ZNF300 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51035557; called by muse, mutect2, varscan2
- ZNF324B | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV60742898; called by muse, mutect2
- ZNF341 | c.2215A>T p.K739* (on ENST00000375200 / NM_001282935.1; = p.K732* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV61010632; called by muse, mutect2, varscan2
- ZNF394 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs367809638; called by muse, mutect2, varscan2
- ZNF433 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV61400091; called by muse, mutect2, varscan2
- ZNF556 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV56913737; called by muse, mutect2, varscan2
- ZNF578 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.628); catalogued as COSV69737349; called by muse, varscan2
- ZNF587 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57149796, COSV57150383; called by muse, mutect2, varscan2
- ZNF662 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60242778; called by muse, mutect2, varscan2
- ZNF765 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV67183221; called by muse, mutect2, varscan2
- ZNF783 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100954267; called by muse, mutect2, varscan2
- ZNF816 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV54412238, COSV99554491; called by muse, mutect2, varscan2
- ZSWIM8 | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV67132919; called by mutect2, varscan2
- C17orf78 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRAK4 | c.535_537del p.N179del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TGDS | c.659_659+5del p.X220_splice | Splice Site (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- ABCC8 | c.3792G>A p.V1264= | Silent (SNP) | VAF 64/197 reads (32%) | catalogued as COSV56855941; called by muse, mutect2, varscan2
- ACTRT2 | c.792C>T p.F264= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs774983376, COSV65759185; called by muse, mutect2, varscan2
- ADAM2 | c.1203G>A p.G401= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1479011461, COSV55866937; called by muse, mutect2, varscan2
- ADAMTS19 | c.1939C>T p.L647= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as COSV50784644; called by muse, mutect2, varscan2
- ADGRF3 | c.1725G>A p.R575= (on ENST00000311519 / NM_001145168.1; = p.R376= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV104410592, COSV61052452; called by muse, mutect2, varscan2
- ADGRG4 | c.7806G>A p.G2602= | Silent (SNP) | VAF 49/62 reads (79%) | catalogued as COSV54963978, COSV54964299; called by muse, mutect2, varscan2
- ADORA3 | c.615G>A p.R205= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99598817; called by muse, mutect2, varscan2
- ADSS2 | c.747C>T p.I249= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV63695119, COSV63695954; called by muse, mutect2, varscan2
- AFF3 | c.2646C>T p.P882= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57843505; called by muse, mutect2
- AGO4 | c.792G>A p.Q264= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV64618302; called by muse, mutect2, varscan2
- ALCAM | c.1659G>A p.K553= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV60253312; called by muse, mutect2, varscan2
- AMFR | c.1080C>T p.F360= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV51923164, COSV51923686; called by muse, mutect2, varscan2
- ANKRD30A | c.1995G>A p.L665= (on ENST00000611781; = p.L609= on NM_052997.2) | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs568154205, COSV64610751; called by muse, mutect2, varscan2
- ANO10 | c.639A>C p.G213= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52735165; called by muse, mutect2, varscan2
- AP4E1 | c.1905G>A p.Q635= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55919395; called by muse, mutect2, varscan2
- ARHGEF10L | c.3204C>A p.V1068= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV51438667; called by muse, varscan2
- ASCC2 | c.2265C>T p.I755= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV57075991; called by muse, mutect2, varscan2
- ASH2L | c.1413C>T p.S471= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as COSV51701386; called by muse, mutect2, varscan2
- BANF1 | c.30C>T p.F10= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV56464023; called by muse, mutect2, varscan2
- BDH1 | c.921C>T p.T307= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV64018479; called by muse, varscan2
- BPIFB4 | c.1450C>T p.L484= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV64952070; called by muse, mutect2, varscan2
- BTN1A1 | c.1521G>A p.R507= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV55069123; called by muse, mutect2, varscan2
- CACNG3 | c.90G>A p.T30= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs767505349, COSV50064101; called by muse, varscan2
- CARMIL3 | c.250C>T p.L84= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV57727961; called by muse, mutect2, varscan2
- CCDC185 | c.1644G>A p.L548= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs867234285, COSV64821652; called by muse, mutect2, varscan2
- CCDC33 | c.1509G>A p.R503= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV51502596; called by muse, mutect2, varscan2
- CCDC80 | c.1467G>A p.K489= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV52820059; called by muse, mutect2, varscan2
- CDCA2 | c.1278C>T p.F426= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV57948030; called by muse, mutect2, varscan2
- CDS1 | c.306G>A p.L102= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV55690281; called by muse, mutect2, varscan2
- CELA3A | c.738C>T p.F246= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV51586347; called by muse, mutect2, varscan2
- CFAP54 | c.5895C>T p.L1965= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1445441775, COSV61574511; called by muse, mutect2, varscan2
- CHD5 | c.1719C>T p.P573= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs756370204, COSV52422663; called by muse, mutect2, varscan2
- CHRM3 | c.1041G>A p.E347= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1382621395, COSV55099337; called by muse, mutect2, varscan2
- CHRM4 | c.1203G>A p.T401= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV58985551; called by muse, mutect2, varscan2
- CLEC3A | c.198C>T p.A66= (on ENST00000651443; = p.A57= on NM_005752.6) | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV55223178; called by muse, mutect2, varscan2
- CMYA5 | c.11889C>T p.S3963= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV69745348, COSV69746091; called by muse, varscan2
- CNBD1 | c.681C>T p.F227= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV72976597; called by muse, mutect2, varscan2
- CNTN4 | c.2724C>T p.I908= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1258186651, COSV61868320; called by muse, mutect2, varscan2
- CNTNAP2 | c.3981G>A p.K1327= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs761292278, COSV62184362; called by muse, mutect2, varscan2
- COL3A1 | c.1308G>A p.K436= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58594858; called by muse, mutect2, varscan2
- COL4A5 | c.666C>T p.F222= | Silent (SNP) | VAF 20/23 reads (87%) | catalogued as COSV60369009; called by muse, mutect2
- COL6A6 | c.5589G>A p.T1863= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs776680243, COSV62034396; called by mutect2, varscan2
- CORO1C | c.1071C>T p.F357= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV54598464, COSV99775796; called by muse, mutect2, varscan2
- CPN2 | c.486G>A p.R162= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV60471050; called by muse, mutect2
- CRB1 | c.555G>A p.L185= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV66346727; called by muse, mutect2, varscan2
- CSE1L | c.1953C>T p.I651= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV53704366; called by muse, mutect2, varscan2
- CSMD2 | c.1134C>T p.S378= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV53949319; called by muse, mutect2, varscan2
- CYP2B6 | c.1281C>T p.I427= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as rs761312899, COSV57845183; called by muse, mutect2, varscan2
- CYP2E1 | c.1293C>T p.S431= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs775511413, COSV53314888; called by muse, mutect2, varscan2
- CYTIP | c.99C>T p.S33= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99938806; called by muse, mutect2, varscan2
- DCAF5 | c.2134C>T p.L712= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as COSV58462397; called by muse, mutect2, varscan2
- DCDC1 | c.4032C>T p.F1344= (on ENST00000597505 / NM_001367979.1; = p.F451= on NM_020869.3) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs763197588, COSV58001949; called by muse, mutect2, varscan2
- DDX19B | c.351G>A p.K117= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV55365595; called by muse, mutect2, varscan2
- DENND2A | c.735G>A p.R245= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV52057190; called by muse, mutect2, varscan2
- DHX37 | c.726C>T p.S242= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV58138456; called by muse, mutect2, varscan2
- DISP2 | c.3621C>T p.P1207= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV51136656; called by muse, mutect2, varscan2
- DPP6 | c.2109G>A p.R703= (on ENST00000377770 / NM_001364500.2; = p.R641= on NM_001936.5) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs767994710, COSV59638510; called by muse, mutect2, varscan2
- DSC1 | c.2373C>T p.S791= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as COSV57142405, COSV57149609; called by muse, mutect2, varscan2
- DSCAM | c.2586C>T p.F862= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV68027079; called by muse, mutect2, varscan2
- DSP | c.6759C>T p.F2253= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV65794797, COSV65794852; called by muse, mutect2, varscan2
- EPPK1 | c.5016C>T p.I1672= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs375624528; called by muse, mutect2, varscan2
- ERC2 | c.2202G>A p.K734= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as COSV55654066; called by muse, mutect2, varscan2
- ERICH3 | c.2493C>T p.I831= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV58615248; called by muse, mutect2, varscan2
- ETV7 | c.513C>T p.F171= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs993711705, COSV60318309; called by mutect2, varscan2
- EXTL3 | c.1017G>C p.R339= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV55039928; called by muse, mutect2, varscan2
- FBXO11 | c.1464T>C p.A488= (on ENST00000403359 / NM_001190274.2; = p.A404= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57024834; called by muse, mutect2, varscan2
- FCGBP | c.6636G>A p.G2212= | Silent (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2, varscan2
- FCGR3B | c.627C>T p.V209= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV54211413, COSV54211444; called by muse, mutect2, varscan2
- FERMT3 | c.183C>T p.D61= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV54182713; called by muse, mutect2, varscan2
- FLT1 | c.2280C>T p.I760= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56738755; called by mutect2, varscan2
- FMN2 | c.1458G>A p.T486= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs920098576, COSV60447916; called by muse, mutect2
- FRG2C | c.681C>T p.S227= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- FRYL | c.5487C>T p.S1829= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV51958306; called by muse, mutect2, varscan2
- GABRR3 | c.153T>C p.D51= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs978563978, COSV72084303; called by muse, mutect2, varscan2
- GAS2L2 | c.2337G>A p.R779= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- GLI2 | c.3588C>T p.S1196= (on ENST00000361492 / NM_001374353.1; = p.S1213= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs769099247, COSV58049184; called by muse, mutect2, varscan2
- GPLD1 | c.1584C>T p.P528= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs200604152, COSV57760200; called by muse, mutect2, varscan2
- GPR158 | c.2406C>T p.S802= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV66279605; called by muse, mutect2, varscan2
- GRIN2A | c.609G>A p.V203= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV58029765; called by muse, mutect2, varscan2
- GRIN2B | c.2502C>T p.I834= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs1348201823, COSV74207315; called by muse, varscan2
- GRM6 | c.1005C>T p.S335= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV51448377; called by muse, mutect2, varscan2
- GRM8 | c.1545C>T p.V515= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs745714130, COSV58858626; called by muse, mutect2, varscan2
- HDLBP | c.711C>T p.I237= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs199516054; called by muse, varscan2
- HELQ | c.102C>T p.L34= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV55027111; called by muse, mutect2, varscan2
- IGHV3-7 | c.192G>A p.L64= | Silent (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- JAGN1 | c.273C>T p.S91= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57062784; called by muse, mutect2, varscan2
- KCNK7 | c.279C>T p.P93= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100442282; called by muse, mutect2
- KIR3DL1 | c.327C>T p.P109= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV58492218, COSV58494984; called by muse, mutect2, varscan2
- KRCC1 | c.474G>A p.Q158= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV61252107; called by muse, mutect2, varscan2
- L1TD1 | c.1713G>A p.K571= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs758340016, COSV63134137; called by muse, mutect2, varscan2
- LCE3D | c.249C>T p.G83= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV64231125; called by muse, mutect2, varscan2
- LILRB1 | c.1386C>T p.P462= (on ENST00000427581; = p.P426= on NM_006669.6) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV61120982; called by muse, mutect2, varscan2
- LNPK | c.234C>T p.L78= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV55825928; called by muse, mutect2, varscan2
- LRIG3 | c.2071C>T p.L691= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV57868551; called by muse, mutect2, varscan2
- LRRC43 | c.1896C>T p.P632= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV57337239; called by muse, mutect2
- LRRC4B | c.804C>T p.I268= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs757109311, COSV65350606; called by muse, mutect2, varscan2
- LRRIQ1 | c.2286G>A p.K762= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as COSV67828859; called by muse, mutect2, varscan2
- LRTM2 | c.891G>A p.Q297= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54566376; called by muse, mutect2, varscan2
- MAPK4 | c.444G>A p.R148= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV68543417; called by muse, mutect2, varscan2
- MASP1 | c.1701C>T p.F567= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as rs147189329; called by muse, mutect2, varscan2
- MCOLN2 | c.1083C>T p.S361= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52298927; called by muse, mutect2, varscan2
- MDK | c.420G>A p.K140= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs775794053, COSV58993680; called by muse, varscan2
- MIXL1 | c.438G>A p.G146= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV64729370; called by muse, mutect2, varscan2
- MME | c.1890C>T p.S630= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV64709726; called by muse, mutect2, varscan2
- MTMR11 | c.1374C>T p.F458= (on ENST00000439741 / NM_001145862.2; = p.F386= on NM_181873.3) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs782651010, COSV54966075; called by muse, mutect2, varscan2
- MTMR8 | c.411G>C p.G137= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV66395819; called by muse, mutect2
- MYO18A | c.1839C>T p.L613= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100572434; called by muse, varscan2
- MYOCD | c.492G>A p.P164= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs745617618, COSV58507592; called by muse, mutect2, varscan2
- MYT1 | c.3261C>T p.F1087= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs202178083, COSV60501696; called by muse, mutect2, varscan2
- NBPF9 | c.1521C>T p.V507= | Silent (SNP) | VAF 76/236 reads (32%) | catalogued as rs782647961, COSV56021062; called by muse, mutect2, varscan2
- NF1 | c.8514C>T p.I2838= (on ENST00000358273 / NM_001042492.3; = p.I2817= on NM_000267.3) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV62195176; called by mutect2, varscan2
- NFIC | c.744C>T p.S248= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs112569402, COSV59415668; called by muse, mutect2, varscan2
- NFKB2 | c.618C>T p.S206= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV50055030; called by muse, mutect2, varscan2
- NLRP2 | c.1977G>A p.K659= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV54759137; called by muse, mutect2, varscan2
- NMD3 | c.549G>A p.Q183= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV63619195; called by muse, mutect2, varscan2
- NWD1 | c.3318G>A p.S1106= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs755764453, COSV60349226; called by muse, mutect2, varscan2
- OR11H1 | c.90C>T p.F30= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as COSV53272461; called by muse, varscan2
- OR14C36 | c.786G>A p.A262= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs143199703, COSV58601678; called by muse, mutect2, varscan2
- OR1A1 | c.858C>T p.F286= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV58403578; called by muse, mutect2, varscan2
- OR2A5 | c.33C>T p.F11= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV101278644, COSV68738722; called by muse, mutect2, varscan2
- OR2F1 | c.879G>A p.R293= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV67330768; called by muse, mutect2, varscan2
- OR2J3 | c.633C>T p.L211= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV65849544; called by muse, varscan2
- OR2T12 | c.624C>T p.P208= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1344369313, COSV58776949, COSV58777448; called by mutect2, varscan2
- OR4K15 | c.231C>T p.S77= (on ENST00000305051; = p.S53= on NM_001005486.1) | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV59303006; called by muse, mutect2, varscan2
- OR5T1 | c.9G>A p.G3= | Silent (SNP) | VAF 69/231 reads (30%) | catalogued as COSV57304367; called by muse, mutect2, varscan2
- OR8H3 | c.480G>A p.V160= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs772985957, COSV100538828, COSV57910915; called by muse, mutect2
- PAPPA | c.4830C>T p.D1610= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV60284333; called by muse, varscan2
- PCCA | c.1011C>T p.F337= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs777777952, COSV66197485; called by mutect2, varscan2
- PCDH18 | c.3174C>T p.A1058= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV61271403; called by muse, mutect2, varscan2
- PCDHB2 | c.681G>T p.T227= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52036423; called by muse, mutect2, varscan2
- PCDHB4 | c.2364C>T p.F788= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs782411165, COSV52025833; called by muse, mutect2, varscan2
- PCDHGB4 | c.1392G>A p.P464= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV54010566; called by muse, mutect2, varscan2
- PEG3 | c.3393G>A p.R1131= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as rs1244236014, COSV55644030; called by muse, mutect2, varscan2
- PHKA1 | c.2958C>T p.I986= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV59809942; called by muse, mutect2, varscan2
- PIK3CB | c.2325G>A p.K775= | Silent (SNP) | VAF 152/540 reads (28%) | catalogued as rs767657138, COSV56689149; called by muse, mutect2, varscan2
- PITPNM1 | c.1827C>T p.P609= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV62707503; called by muse, mutect2, varscan2
- PIWIL2 | c.2355G>A p.V785= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV63253537; called by muse, mutect2, varscan2
- PKP1 | c.162C>T p.S54= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV55824331; called by muse, mutect2
- PLEC | c.11478G>A p.T3826= (on ENST00000322810 / NM_201380.4; = p.T3716= on NM_000445.5) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs781847790, COSV100519742, COSV59680962; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPRC1 | c.4371C>T p.S1457= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1251792067, COSV53387781; called by muse, mutect2, varscan2
- PRAMEF18 | c.477C>T p.F159= | Silent (SNP) | VAF 77/550 reads (14%) | called by muse, mutect2, varscan2
- PRR15L | c.123G>A p.R41= | Silent (SNP) | VAF 86/142 reads (61%) | catalogued as COSV99846530; called by muse, varscan2
- PRSS38 | c.528G>A p.V176= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as rs1303728072, COSV64541559; called by muse, mutect2, varscan2
- PSG1 | c.783C>T p.T261= | Silent (SNP) | VAF 69/213 reads (32%) | catalogued as COSV54955680; called by muse, mutect2, varscan2
- PTCHD3 | c.2019G>A p.R673= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs145775010; called by muse, mutect2, varscan2
- PTDSS2 | c.429C>T p.L143= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as COSV57279595; called by muse, mutect2, varscan2
- PTPRD | c.2358C>T p.I786= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV61973901; called by muse, mutect2, varscan2
- QARS1 | c.678G>A p.G226= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs998738716, COSV60275937; called by muse, mutect2, varscan2
- RAB40B | c.519C>T p.I173= | Silent (SNP) | VAF 53/87 reads (61%) | catalogued as rs142445256; called by muse, varscan2
- RAB40C | c.786C>T p.S262= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs139898602; called by muse, varscan2
- RFPL1 | c.435G>A p.R145= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100585830; called by muse, mutect2, varscan2
- RORC | c.636G>A p.E212= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs749564698, COSV59094995; called by muse, mutect2, varscan2
- RSPH14 | c.783C>T p.I261= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV53271293; called by muse, mutect2
- RUBCN | c.1080G>A p.Q360= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV56372195; called by muse, mutect2, varscan2
- SALL1 | c.1857C>T p.P619= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs767905804, COSV51762949; called by muse, mutect2, varscan2
- SAMD4B | c.165C>T p.I55= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58752953; called by muse, mutect2, varscan2
- SATB1 | c.2013C>T p.D671= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs776065234, COSV58671216; called by muse, mutect2, varscan2
- SBF1 | c.346C>T p.L116= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV62369926; called by muse, mutect2, varscan2
- SCN11A | c.4170A>G p.Q1390= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV56573403; called by muse, mutect2, varscan2
- SCPEP1 | c.285C>T p.D95= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV51855307; called by muse, mutect2, varscan2
- SDR42E1 | c.927C>T p.P309= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV61094928; called by muse, mutect2, varscan2
- SEC14L4 | c.645G>A p.R215= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55401146; called by muse, mutect2, varscan2
- SEC14L4 | c.183G>A p.E61= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV55401159; called by muse, mutect2, varscan2
- SERPINB8 | c.801C>T p.F267= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs771394223, COSV54640439; called by muse, varscan2
- SIGLEC9 | c.813C>T p.V271= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV51587208; called by muse, mutect2, varscan2
- SIN3B | c.786C>T p.T262= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs937280188, COSV99931863; called by muse, mutect2, varscan2
- SLC22A5 | c.1401C>T p.S467= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1449055165, COSV99809933, COSV99810027; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC52A2 | c.979C>T p.L327= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV57351739, COSV57353140; called by muse, varscan2
- SLC6A19 | c.840C>T p.S280= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs774578806, COSV58673475; called by muse, mutect2
- SLC7A13 | c.102C>T p.S34= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV52538164, COSV99878600; called by muse, mutect2, varscan2
- SLC9A9 | c.669C>T p.F223= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57241339; called by muse, mutect2, varscan2
- SLCO1B3 | c.1842G>A p.R614= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs1417169342, COSV53934310; called by muse, mutect2, varscan2
- SPHKAP | c.1578G>A p.S526= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs376372743; called by muse, mutect2, varscan2
- SPRR4 | c.177C>T p.T59= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV60143169; called by muse, mutect2, varscan2
- SPTB | c.6105G>A p.G2035= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV61552543; called by muse, mutect2, varscan2
- ST3GAL6 | c.486C>T p.T162= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1230503175, COSV99505058; called by muse, mutect2, varscan2
- ST6GAL2 | c.1485G>A p.L495= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV62417836; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.573C>T p.L191= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as rs555085022, COSV59570481; called by muse, mutect2, varscan2
- STAB2 | c.1893G>A p.V631= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV66345056; called by muse, mutect2, varscan2
- STAP1 | c.867G>A p.K289= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV55329947; called by muse, mutect2, varscan2
- SYN1 | c.396G>A p.G132= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs375837996, COSV55984163; called by muse, mutect2, varscan2
- SYNGAP1 | c.1881C>T p.A627= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53385548; called by muse, mutect2
- TCAF1 | c.231C>A p.L77= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV63518674; called by mutect2, varscan2
- TCAF2 | c.966C>T p.S322= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100633650; called by mutect2, varscan2
- TECTA | c.5550C>T p.I1850= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV50777243, COSV50805657; called by muse, mutect2, varscan2
- TENM2 | c.2931C>T p.S977= (on ENST00000518659 / NM_001122679.2; = p.S745= on NM_001080428.3) | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV69130912; called by muse, mutect2, varscan2
- TEX55 | c.801G>A p.R267= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV55212506; called by muse, mutect2
- TMEM104 | c.657C>T p.L219= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as rs1010580818, COSV59111615; called by muse, mutect2, varscan2
- TMEM132A | c.2727G>A p.L909= (on ENST00000453848 / NM_178031.3; = p.L910= on NM_017870.4) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV50018017; called by muse, mutect2, varscan2
- TMEM40 | c.288G>A p.G96= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53148123; called by muse, mutect2, varscan2
- TMPRSS15 | c.1500G>A p.G500= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV53034978, COSV53036761; called by muse, mutect2, varscan2
- TNIP1 | c.453C>T p.P151= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV59309604; called by muse, mutect2
- TNNI3 | c.558G>A p.R186= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV52573162; called by muse, mutect2, varscan2
- TRAV30 | c.195C>T p.F65= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- TRIM35 | c.738G>A p.K246= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100542820; called by muse, varscan2
- TSPAN32 | c.651C>T p.S217= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1367868534, COSV99478287; called by muse, mutect2, varscan2
- TTN | c.26796G>A p.T8932= (on ENST00000591111; = p.T8005= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs778970711, COSV60274643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAT1L | c.939C>T p.I313= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs200017287, COSV56815161; called by muse, mutect2, varscan2
- VILL | c.1371G>A p.E457= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV52187293; called by muse, mutect2, varscan2
- VTCN1 | c.654G>A p.T218= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs773797959, COSV60224885; called by muse, mutect2, varscan2
- WDR93 | c.1890G>A p.R630= | Silent (SNP) | VAF 76/240 reads (32%) | catalogued as COSV51530643; called by muse, mutect2, varscan2
- WNT10A | c.408C>T p.I136= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs201117517, COSV51462291; called by muse, mutect2, varscan2
- YIPF7 | c.234A>T p.S78= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV60657860; called by muse, mutect2, varscan2
- ZBTB46 | c.1023C>T p.L341= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV55513183; called by muse, mutect2, varscan2
- ZFP3 | c.732G>A p.Q244= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100603721, COSV59583813; called by muse, mutect2, varscan2
- ZNF211 | c.1215C>T p.S405= (on ENST00000347302 / NM_198855.4; = p.S418= on NM_006385.5) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV53744694; called by muse, mutect2
- ZNF275 | c.186G>A p.Q62= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs782654309, COSV100936349, COSV100936487; called by muse, mutect2, varscan2
- ZNF276 | c.636C>T p.A212= (on ENST00000443381 / NM_001113525.2; = p.A137= on NM_152287.4) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs540321841, COSV57066564, COSV57072152; called by muse, mutect2, varscan2
- ZNF394 | c.963C>T p.F321= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100529922; called by muse, mutect2, varscan2
- ZNF438 | c.336C>T p.S112= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV59199585; called by muse, mutect2, varscan2
- ZNF462 | c.3972C>T p.P1324= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV52948516; called by muse, mutect2, varscan2
- ZNF653 | c.1527C>T p.F509= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV53402217, COSV53404372; called by muse, mutect2, varscan2
- ZNF665 | c.1119C>T p.A373= (on ENST00000600412; = p.A438= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV67216876; called by muse, mutect2, varscan2
- ZNF783 | c.339G>A p.L113= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs374722393; called by muse, mutect2, varscan2
- ZSWIM8 | c.2145C>G p.T715= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs765066839, COSV101290026; called by muse, mutect2, varscan2
- BAX | c.474+65C>T | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99509160; called by muse, mutect2, varscan2
- CACNA1C | c.3829-629A>C | Intron (SNP) | VAF 33/122 reads (27%) | catalogued as COSV59758466; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2488C>T | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100153870; called by muse, mutect2, varscan2
- FAM183BP | n.1236G>A | RNA (SNP) | VAF 45/141 reads (32%) | catalogued as rs777801963; called by muse, varscan2
- FXYD6P3 | n.145C>T | RNA (SNP) | VAF 8/11 reads (73%) | catalogued as rs980728529; called by muse, varscan2
- HDAC9 | c.2577+14C>T | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as rs751640170, COSV67770533; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.176C>T | RNA (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- MACROD2 | c.418+165077G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs867624902; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.726C>T | RNA (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- MIR1253 | n.78C>T | RNA (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- MIR329-2 | n.17G>A | RNA (SNP) | VAF 22/77 reads (29%) | catalogued as rs1288955690; called by muse, mutect2, varscan2
- MSR1 | c.1033+2533C>T | Intron (SNP) | VAF 37/104 reads (36%) | catalogued as COSV100027562; called by muse, mutect2, varscan2
- SERPINA13P | n.962G>A | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as rs751567044; called by muse, mutect2, varscan2
- UBTFL2 | n.933G>A | RNA (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- UBTFL2 | n.307C>T | RNA (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
